Somatic mutation profile of tumor specimen 0DM8UC from CCDI case PBBZZV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.1 years (750 days).
Specimen 0DM8UC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cdc14469-127d-4e75-937f-1ada81c98d28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM8U4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9a6d605-a17e-4662-ab95-4ae64ef6c1a9

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 3, Silent 2, Frame Shift Del 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 674/1663 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- DDX60 | c.4306G>T p.A1436S | Missense Mutation (SNP) | VAF 200/1145 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.259); catalogued as rs867583844; called by muse, varscan2
- ETS1 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 132/1578 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.239); catalogued as COSV60093671; called by muse, mutect2
- ITPR2 | c.6863G>A p.R2288Q | Missense Mutation (SNP) | VAF 316/1950 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as rs773496161; called by muse, mutect2, varscan2
- KLHDC8B | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 396/972 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0.038); catalogued as rs756357057, COSV60412528; called by muse, mutect2, varscan2
- LPAR4 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 873/2460 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472738201, COSV70912902; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 58/2084 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 46/1670 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- INSM1 | c.149_174del p.P50Rfs*280 | Frame Shift Del (DEL) | VAF 93/416 reads (22%) | called by mutect2, pindel, varscan2
- PTCH1 | c.3125_3130dup p.V1042_C1043dup | In Frame Ins (INS) | VAF 628/1587 reads (40%) | called by mutect2, varscan2
- PTCH1 | c.479_483del p.Q160Pfs*2 | Frame Shift Del (DEL) | VAF 429/1011 reads (42%) | called by mutect2, pindel, varscan2
- LRRK2 | c.6855T>A p.A2285= | Silent (SNP) | VAF 38/1608 reads (2%) | called by muse, mutect2
- POMGNT2 | c.483C>T p.P161= | Silent (SNP) | VAF 533/1252 reads (43%) | catalogued as rs548747822, COSV60953583; called by muse, mutect2, varscan2
- CXCR3 | c.13-135G>A | Intron (SNP) | VAF 384/1123 reads (34%) | called by muse, mutect2, varscan2
- MR1 | c.604+98C>A | Intron (SNP) | VAF 20/436 reads (5%) | called by muse, mutect2
- PKD1 | c.2985+98C>T | Intron (SNP) | VAF 102/312 reads (33%) | catalogued as rs559717259; called by muse, mutect2, varscan2
